TCGA case TCGA-DH-5143 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: University of Florida. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dcd0856d-423a-40d7-8070-4c0988d61416

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 30 years; Vital status: Alive.

Diagnoses (1)
1. Mixed glioma: ICD-O-3 morphology code: 9382/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 30.9 years (11,291 days); Year of diagnosis: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,401 days (3.8 years); First symptom longest duration: 91-180 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Temporal lobe; Supratentorial localization: Cerebral Cortex.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 64 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 64 days; Number of cycles: 1; Treatment dose: 3,000 mg/m2; Prescribed dose: 75; Prescribed dose units: mg/m2/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 95 days; Days to treatment end: 99 days; Number of cycles: 1; Treatment dose: 1,500 mg; Prescribed dose: 300; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 123 days; Number of cycles: 12; Treatment outcome: Treatment Ongoing; Prescribed dose: 200; Prescribed dose units: mg/m2/day; Route of administration: Oral.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.

Follow-up (3 entries)
- Day 13 (prior to adjuvant therapy): Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 438 days (1.2 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 1,401.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Altered Mental Status / Seizure.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DH-5143-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.7.
  Slide TCGA-DH-5143-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-DH-5143-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-DH-5143-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DH-5143-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligoastrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy; Tumor site: Supratentorial, Temporal Lobe; History seizures: Yes; History headaches: No; Symp changes mental status: Yes; Symp changes visual: No; First symptom longest duration: 91 - 180 Days; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: Yes; Idh1 mutation test indicator: No.
- Drug treatment 1: Regimen number: 3.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 2.
- Drug treatment 3: Regimen number: 1.
- Follow-up form 1: Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: No; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form 2: Lost to follow-up: Yes; Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: No; Treatment outcome at TCGA followup: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,401 days; disease-specific survival: no event (censored), 1,401 days; progression-free interval: no event (censored), 1,401 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DH-5143-01A-01D-1466-01): tumor purity 0.29, ploidy 3.97, whole-genome doublings 1.
